CGCI case HTMCP-01-01-00002 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08300ffb-ab9a-49bb-b741-7df60b293d62

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 0 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 51.1 years (18,679 days); Year of diagnosis: 2006; Method of diagnosis: Autopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Pericardium; Sites of involvement: Heart / Pericardium.
   Pathology details: Lymph node involved site: Mediastinal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Negative.
- CD3 (IHC): Negative.
- CD79A (IHC): Negative.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Equivocal; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Day 0: Nadir CD4 count: 124.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Haart treatment indicator: Yes.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Biospecimens (2 samples)
- Sample HTMCP-01-01-00002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-01-00002-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Year of HIV diagnosis: 1987; Haart therapy prior to diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Heart.
- Primary pathology: Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: At Autopsy; Lymph nodes examined: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220629.xlsx, for sample HTMCP-01-01-00002-01A-01D-111:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220629.xlsx, for sample HTMCP-01-01-00002-01A-01R-111:
- % tumour top: 90
- % tumour bottom: 90
